Somatic mutation profile of tumor specimen TCGA-DA-A3F8-06A (aliquot TCGA-DA-A3F8-06A-11D-A20D-08) from TCGA case TCGA-DA-A3F8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 39.3 years (14,353 days).
Specimen TCGA-DA-A3F8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6967c889-ba3d-499d-957b-5a425e8d7bc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A3F8-10A (Blood Derived Normal), aliquot TCGA-DA-A3F8-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cf048b7-56bd-4556-8007-82e0e1fe6f5e

The open-access MAF lists 1,425 somatic variants for this specimen: 917 protein-altering or splice-affecting, 483 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 829, Silent 483, Nonsense Mutation 50, Splice Site 15, Splice Region 14, Intron 10, RNA 8, 3'UTR 4, Translation Start Site 3, Frame Shift Del 3, 5'Flank 2, Frame Shift Ins 2.

Variants (750 of 1,425; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CLEC14A | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs1470716755, COSV60561634; called by muse, mutect2, varscan2
- FRMD4B | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV68328045; called by muse, mutect2, varscan2
- HSD17B4 | c.1613C>T p.P538L (on ENST00000414835 / NM_001199291.3; = p.P513L on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs587777444, COSV56333739; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- LDLR | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs773658037, CM011396, CM103826, CM981191, COSV52941747; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP6C | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763733111, COSV65207035; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPGRIP1 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs565837539, CM1312225, COSV52845281; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775623976, COSV59205859, COSV59212489, COSV59228873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC6A1 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | catalogued as rs1559626646, COSV55113334; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AACS | c.134-1G>A p.X45_splice | Splice Site (SNP) | VAF 16/68 reads (24%) | catalogued as COSV55534604; called by muse, mutect2, varscan2
- ABCA10 | c.2590C>T p.P864S | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.223); catalogued as COSV52218555; called by muse, mutect2, varscan2
- ABCA2 | c.4411C>T p.H1471Y (on ENST00000614293; = p.H1441Y on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV55797850; called by muse, mutect2, varscan2
- ABCA3 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as rs148726153; called by muse, mutect2, varscan2
- ABCA4 | c.5887C>T p.R1963C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs777887467, COSV64671225; called by muse, mutect2, varscan2
- ABCC2 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV64984671; called by muse, mutect2, varscan2
- AC006059.2 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs761195669, COSV59605832; called by muse, mutect2, varscan2
- ACIN1 | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52973552; called by muse, mutect2, varscan2
- ACKR2 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV56176842; called by muse, mutect2, varscan2
- ACOX1 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV53131453; called by muse, mutect2, varscan2
- ACSM2A | c.763G>A p.D255N (on ENST00000219054; = p.D176N on NM_001308169.2) | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54582416, COSV54582767; called by muse, mutect2, varscan2
- ADAM18 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs865870698, COSV55844130; called by muse, mutect2, varscan2
- ADAM21 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV50788825; called by muse, mutect2, varscan2
- ADAM21 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV50788840; called by muse, mutect2, varscan2
- ADAM7 | c.2056C>T p.L686F | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV51535407; called by muse, mutect2
- ADAMTS12 | c.3341C>T p.T1114I | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1416825212, COSV61256146; called by muse, mutect2, varscan2
- ADAMTS19 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV50732890; called by muse, mutect2, varscan2
- ADAMTS19 | c.2096G>A p.R699K | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50732906, COSV99176182; called by muse, mutect2, varscan2
- ADAR | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52712459; called by muse, mutect2, varscan2
- ADCY1 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1490066336, COSV52030543; called by muse, mutect2, varscan2
- ADCY6 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs1403038648; called by muse, mutect2, varscan2
- ADD2 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV52455336; called by muse, mutect2, varscan2
- ADGRB3 | c.3673G>A p.E1225K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV53235405; called by muse, mutect2, varscan2
- ADGRE1 | c.1679G>A p.G560E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51672363; called by muse, mutect2, varscan2
- ADH1A | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.561); catalogued as COSV52924337; called by muse, mutect2, varscan2
- ADIPOQ | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57858504; called by muse, mutect2, varscan2
- ADNP2 | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV51536346; called by muse, varscan2
- ADORA3 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1428233076, COSV53985023; called by muse, mutect2, varscan2
- ADSS1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 80/319 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV58272097; called by muse, mutect2, varscan2
- AGRN | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65067875; called by muse, mutect2, varscan2
- AKAP13 | c.3540C>G p.D1180E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV63449159; called by muse, mutect2, varscan2
- AKIP1 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as rs771060497, COSV55148533; called by muse, mutect2, varscan2
- AKR1D1 | c.818A>G p.K273R | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV54336269; called by muse, mutect2, varscan2
- AL592490.1 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 22/138 reads (16%) | catalogued as COSV69424679; called by muse, mutect2, varscan2
- AL645922.1 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 85/456 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54959397; called by muse, mutect2, varscan2
- AMIGO2 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs866149480, COSV56973369; called by muse, mutect2, varscan2
- ANK3 | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 36/151 reads (24%) | catalogued as COSV55045350; called by muse, mutect2, varscan2
- ANKFN1 | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as rs201192117, COSV59441444; called by muse, mutect2, varscan2
- ANKRD22 | c.499-1G>A p.X167_splice | Splice Site (SNP) | VAF 27/107 reads (25%) | catalogued as COSV64237634; called by muse, mutect2, varscan2
- ANKS4B | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs531162767, COSV61138806; called by muse, mutect2, varscan2
- APCS | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54817288; called by muse, mutect2
- APOB | c.12040G>A p.D4014N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV51924420; called by muse, mutect2, varscan2
- APOH | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); catalogued as rs55645281, COSV52771453; called by muse, mutect2, varscan2
- ARHGAP20 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs746235944, COSV52806977; called by muse, mutect2, varscan2
- ARHGAP29 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1299495644, COSV53108702; called by muse, mutect2, varscan2
- ARHGAP29 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53108724; called by muse, mutect2, varscan2
- ARHGAP5 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as COSV61534092; called by muse, mutect2, varscan2
- ARHGEF15 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV62724407; called by muse, mutect2, varscan2
- ARHGEF18 | c.3187+2T>C p.X1063_splice (on ENST00000359920 / NM_001130955.2; = p.X959_splice on NM_015318.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 35/150 reads (23%) | catalogued as COSV60467168; called by muse, mutect2, varscan2
- ARHGEF6 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as COSV51687711; called by muse, mutect2, varscan2
- ARID4A | c.3401C>T p.P1134L | Missense Mutation (SNP) | VAF 77/358 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV62162107; called by muse, mutect2, varscan2
- ARL14EP | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV56342298; called by muse, mutect2, varscan2
- ARL8B | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.48); catalogued as rs762303414, COSV56577157; called by muse, mutect2, varscan2
- ARNTL2 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53823589; called by muse, mutect2, varscan2
- ARPP21 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); catalogued as COSV51792572; called by muse, mutect2, varscan2
- ARPP21 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs773951846, COSV51809002; called by muse, mutect2, varscan2
- ARSJ | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as rs747250767, COSV59536786; called by muse, mutect2, varscan2
- ASB17 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV52409383; called by muse, mutect2
- ASTN1 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.893); catalogued as COSV56062078; called by muse, mutect2, varscan2
- ASXL3 | c.5666T>C p.V1889A | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52458090; called by muse, mutect2, varscan2
- ATP12A | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54512696; called by muse, mutect2, varscan2
- ATP13A3 | c.2561C>T p.T854I | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV55461775; called by muse, mutect2, varscan2
- ATP13A5 | c.2151G>A p.M717I | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs267599736, COSV60866095; called by muse, mutect2, varscan2
- ATP13A5 | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60866119; called by muse, mutect2, varscan2
- ATRN | c.548G>A p.W183* | Nonsense Mutation (SNP) | VAF 69/337 reads (20%) | catalogued as COSV53524153; called by muse, mutect2, varscan2
- AURKB | c.753T>G p.N251K | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV60243545; called by muse, mutect2, varscan2
- BARX2 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV55649400; called by muse, mutect2, varscan2
- BBS9 | c.2020C>T p.R674W (on ENST00000242067 / NM_001348036.1; = p.R634W on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368526968; called by muse, mutect2, varscan2
- BCAS1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV65083961; called by muse, mutect2, varscan2
- BCL11B | c.2107C>T p.P703S (on ENST00000357195 / NM_001282237.2; = p.P632S on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.119); catalogued as rs754658390, COSV61733517; called by muse, mutect2, varscan2
- BEST3 | c.820C>T p.P274S | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58299015; called by muse, mutect2, varscan2
- BNIP2 | c.574A>G p.K192E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.781); catalogued as COSV51105136; called by muse, mutect2, varscan2
- BPIFB2 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs150536106, COSV50063165; called by muse, mutect2, varscan2
- BRCA1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.878); catalogued as COSV100523346, COSV58784345; called by muse, mutect2, varscan2
- BRINP3 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 40/247 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV66514384, COSV66531266; called by muse, mutect2, varscan2
- BSN | c.3928C>T p.P1310S | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56528317; called by muse, mutect2, varscan2
- C10orf71 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV60504772; called by muse, mutect2, varscan2
- C1orf174 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs774822999, COSV64365640; called by muse, mutect2, varscan2
- C21orf91 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53032451; called by muse, mutect2, varscan2
- C6 | c.2700G>A p.M900I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs936346082, COSV54705435; called by muse, mutect2, varscan2
- C6 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54704604; called by muse, mutect2
- C7 | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV57471146, COSV57474846; called by muse, mutect2
- C8A | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940831429, COSV63483165; called by muse, mutect2, varscan2
- C9 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as COSV54674397, COSV54677915; called by muse, mutect2, varscan2
- CAB39L | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as COSV61713693; called by muse, mutect2
- CABS1 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.177); catalogued as rs1366967060, COSV56732995, COSV56733238; called by muse, mutect2, varscan2
- CACNA1E | c.3235C>T p.P1079S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1007809575, COSV100706329, COSV62383244; called by muse, mutect2, varscan2
- CACNA1H | c.4479C>T p.A1493= | Splice Region (SNP) | VAF 10/90 reads (11%) | catalogued as COSV61984343; called by mutect2, varscan2
- CACNA1S | c.2980G>A p.D994N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as rs369941827; called by muse, mutect2, varscan2
- CACNA2D3 | c.3077C>T p.T1026I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.313); catalogued as COSV55516736; called by muse, mutect2, varscan2
- CACNG1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56826124; called by muse, mutect2, varscan2
- CACNG5 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.954); catalogued as COSV50054699, COSV50054783; called by muse, mutect2, varscan2
- CADM3 | c.166G>A p.E56K (on ENST00000368125 / NM_001127173.3; = p.E90K on NM_021189.5) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as rs372984577, COSV63684027; called by muse, mutect2, varscan2
- CADM4 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55928197; called by muse, mutect2, varscan2
- CALCOCO1 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs150332172; called by muse, mutect2, varscan2
- CALHM5 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1017506632, COSV100635667, COSV62067327; called by muse, mutect2, varscan2
- CAMK4 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56662944, COSV56675908; called by muse, mutect2, varscan2
- CAMSAP3 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.113); catalogued as COSV50331018; called by muse, mutect2, varscan2
- CARD11 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.342); catalogued as rs867239716, COSV62754120, COSV62755488; called by muse, mutect2, varscan2
- CASP14 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.398); catalogued as COSV55664830; called by muse, mutect2, varscan2
- CASP5 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV52826807; called by muse, mutect2, varscan2
- CBFA2T2 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60797147; called by muse, mutect2, varscan2
- CCBE1 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs1044732773, COSV67949228; called by muse, mutect2, varscan2
- CCDC102B | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as rs772524331, COSV60135042; called by muse, mutect2
- CCDC30 | c.1706G>A p.R569Q (on ENST00000340612; = p.R526Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs774841907, COSV59604562; called by muse, mutect2, varscan2
- CCR2 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 48/177 reads (27%) | catalogued as COSV52747735; called by muse, mutect2, varscan2
- CD177 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs1291450592, COSV65120845; called by muse, mutect2, varscan2
- CD1B | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV63803821; called by muse, varscan2
- CD1E | c.1015C>T p.L339F | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1315932033, COSV63770070; called by muse, mutect2, varscan2
- CD200 | c.605C>T p.S202L (on ENST00000473539 / NM_001004196.3; = p.S177L on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV59862235; called by muse, mutect2, varscan2
- CD300C | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV58169639; called by muse, mutect2, varscan2
- CD300C | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58169654; called by muse, mutect2, varscan2
- CD33 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs778906989, COSV51800103; called by muse, mutect2, varscan2
- CD37 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.273); catalogued as COSV60543392; called by muse, mutect2, varscan2
- CD8A | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as COSV52156479; called by muse, mutect2, varscan2
- CDC25A | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 46/287 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs374368943, COSV56769636; called by muse, mutect2, varscan2
- CEACAM20 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.202); catalogued as COSV57600881; called by muse, mutect2
- CELSR3 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV50840456; called by muse, mutect2, varscan2
- CENPK | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV54467300; called by muse, mutect2, varscan2
- CER1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.417); catalogued as COSV66602918; called by muse, mutect2, varscan2
- CFAP299 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV63871338; called by muse, mutect2, varscan2
- CFAP47 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.03); catalogued as COSV52881044; called by muse, mutect2, varscan2
- CFAP54 | c.5471G>A p.R1824Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs558062906, COSV61570271; called by muse, mutect2, varscan2
- CFAP65 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV55389509; called by muse, mutect2, varscan2
- CFTR | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV50041592; called by muse, mutect2
- CHCHD4 | c.184G>A p.G62S (on ENST00000396914 / NM_001098502.2; = p.G75S on NM_144636.3) | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777353604, COSV55499552; called by muse, mutect2, varscan2
- CHD2 | c.4757C>T p.S1586F | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67706881; called by muse, mutect2, varscan2
- CHPF2 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV50389129; called by muse, mutect2, varscan2
- CHRD | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.124); catalogued as COSV52605681; called by muse, mutect2, varscan2
- CHRD | c.2556G>A p.V852= | Splice Region (SNP) | VAF 66/243 reads (27%) | catalogued as COSV52605693; called by muse, mutect2, varscan2
- CHRNB3 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1418024205, COSV51493359, COSV51495659; called by muse, mutect2, varscan2
- CHST4 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58296522; called by muse, mutect2, varscan2
- CHSY3 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1157855660; called by muse, mutect2
- CHSY3 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); catalogued as rs1385789971; called by muse, mutect2
- CIC | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as rs1353068686, COSV50547934; called by muse, mutect2, varscan2
- CKAP5 | c.5905C>T p.P1969S (on ENST00000529230 / NM_001008938.4; = p.P1909S on NM_014756.3) | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs1490170283, COSV56364405; called by muse, mutect2, varscan2
- CLEC17A | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60426849; called by muse, varscan2
- CLEC17A | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV60426865; called by muse, varscan2
- CLSTN2 | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as COSV71718316; called by muse, mutect2, varscan2
- CNGA4 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66005155; called by muse, mutect2, varscan2
- CNGB3 | c.567G>A p.W189* | Nonsense Mutation (SNP) | VAF 26/128 reads (20%) | catalogued as COSV60685105; called by muse, mutect2, varscan2
- CNTNAP2 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62147972; called by muse, mutect2, varscan2
- CNTNAP2 | c.3700G>A p.D1234N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV62147976, COSV62163752; called by muse, mutect2, varscan2
- CNTNAP3 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV52663134; called by muse, mutect2
- CNTNAP5 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV70474102; called by muse, mutect2, varscan2
- CNTNAP5 | c.3868G>A p.E1290K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV70474105, COSV70495341; called by muse, mutect2, varscan2
- COL15A1 | c.3817C>T p.L1273F | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV66641489; called by muse, mutect2, varscan2
- COL19A1 | c.3257C>T p.P1086L | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.563); catalogued as COSV59565932; called by muse, mutect2
- COL1A2 | c.542G>A p.G181E | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51953311; called by muse, mutect2, varscan2
- COL21A1 | c.1914T>A p.G638= | Splice Region (SNP) | VAF 8/75 reads (11%) | catalogued as COSV55154333; called by muse, mutect2, varscan2
- COL21A1 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs267601087, COSV55152247; called by muse, mutect2, varscan2
- COL22A1 | c.3236G>A p.R1079Q | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146190475; called by muse, mutect2, varscan2
- COL4A4 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.795); catalogued as rs267599229, COSV61629779; called by muse, mutect2, varscan2
- COL6A6 | c.3119G>A p.G1040E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62018420; called by muse, mutect2, varscan2
- COL9A3 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.985); catalogued as rs772379246, COSV58983279; called by muse, mutect2, varscan2
- COLEC10 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs142250367, COSV60520636; called by muse, mutect2
- CPA1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs900864227, COSV50568146; called by muse, mutect2
- CPA3 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.454); catalogued as rs866956006, COSV56043518, COSV56044469; called by muse, mutect2, varscan2
- CRB2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1029522938, COSV63501834, COSV63503401; called by muse, mutect2, varscan2
- CREB5 | c.331G>A p.G111R (on ENST00000357727 / NM_182898.4; = p.G104R on NM_004904.3) | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.151); catalogued as COSV63217635; called by muse, mutect2, varscan2
- CRYBG1 | c.2861T>C p.L954P | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV64810841; called by muse, mutect2, varscan2
- CRYBG3 | c.7997C>T p.P2666L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs572414094, COSV51709649, COSV99476988; called by muse, mutect2
- CSH2 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 21/138 reads (15%) | catalogued as COSV61080066; called by muse, mutect2, varscan2
- CSMD1 | c.9856G>A p.D3286N (on ENST00000520002; = p.D3285N on NM_033225.6) | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.995); catalogued as COSV59284751; called by muse, mutect2, varscan2
- CSMD1 | c.8744G>A p.G2915E (on ENST00000520002; = p.G2914E on NM_033225.6) | Missense Mutation (SNP) | VAF 59/293 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV59284780; called by muse, mutect2, varscan2
- CSMD1 | c.7880C>T p.S2627F (on ENST00000520002; = p.S2626F on NM_033225.6) | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs267601891, COSV59284813; called by muse, mutect2, varscan2
- CSMD1 | c.2176G>A p.D726N (on ENST00000520002; = p.D725N on NM_033225.6) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59284848; called by muse, mutect2, varscan2
- CSMD2 | c.9005G>A p.G3002E | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV53882695; called by muse, mutect2, varscan2
- CST9L | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866228123, COSV65407576; called by muse, mutect2, varscan2
- CTIF | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 61/416 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56480122; called by muse, mutect2, varscan2
- CTNNBL1 | c.506C>G p.T169R | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1254408001, COSV63743780; called by muse, mutect2, varscan2
- CTNND2 | c.2315C>T p.S772L | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs867204139, COSV58867189; called by muse, varscan2
- CTSA | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51945417; called by muse, mutect2, varscan2
- CTSG | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1229621689, COSV53534692, COSV99361647; called by muse, mutect2, varscan2
- CXCL10 | c.100A>G p.S34G | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV60660763; called by muse, mutect2, varscan2
- CYP27A1 | c.734G>A p.G245E | Missense Mutation (SNP) | VAF 284/715 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV51467084; called by muse, mutect2, varscan2
- CYP2C18 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1278639064, COSV53669848; called by muse, mutect2, varscan2
- CYP2C8 | c.750A>C p.E250D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs1192688346, COSV64876138; called by muse, mutect2, varscan2
- CYP2F1 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as COSV58526711; called by muse, mutect2, varscan2
- CYP3A43 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV55934841; called by muse, mutect2
- CYP3A7-CYP3A51P | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.068); catalogued as rs1477957460; called by muse, mutect2
- CYP4A11 | c.636G>A p.R212= | Splice Region (SNP) | VAF 12/110 reads (11%) | catalogued as COSV60222212; called by muse, mutect2, varscan2
- CYP4F11 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV56125737; called by muse, mutect2, varscan2
- CYP4F11 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV56125747, COSV56128506; called by muse, mutect2, varscan2
- CYP7B1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV59582903; called by muse, varscan2
- CYP7B1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs866340497, COSV59582915; called by muse, varscan2
- DAB1 | c.1348G>A p.D450N (on ENST00000371231; = p.D417N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as COSV64690418; called by muse, mutect2, varscan2
- DACH2 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs149971925, COSV64162426, COSV64168288; called by muse, mutect2, varscan2
- DCAF5 | c.2213C>T p.P738L | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV58458616; called by muse, mutect2, varscan2
- DCTN1 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs149526947, COSV62619711; called by muse, mutect2, varscan2
- DCX | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV57566206; called by muse, mutect2, varscan2
- DDHD2 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV68157238; called by muse, mutect2, varscan2
- DDX3X | c.596A>C p.Y199S (on ENST00000399959; = p.Y200S on NM_001356.5) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863123; called by muse, mutect2, varscan2
- DDX5 | c.727A>G p.T243A | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV56747982; called by muse, mutect2, varscan2
- DDX60 | c.4852C>T p.R1618C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as rs367640779; called by muse, mutect2, varscan2
- DDX60L | c.953T>A p.I318N | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52708952; called by muse, mutect2
- DEFB1 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV52412706; called by muse, mutect2, varscan2
- DEFB104A | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV100055446; called by mutect2, varscan2
- DGAT2 | c.299G>T p.W100L | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57175349; called by muse, mutect2, varscan2
- DGLUCY | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs773652682, COSV56364555; called by muse, mutect2, varscan2
- DHRS2 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as rs200606561, COSV51630568; called by muse, mutect2, varscan2
- DHX38 | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51696383; called by muse, mutect2, varscan2
- DIRAS1 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV60215010; called by muse, mutect2, varscan2
- DLGAP4 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs780267140, COSV59414654; called by muse, mutect2, varscan2
- DLK2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs142658388; called by muse, mutect2, varscan2
- DNAH1 | c.6899C>T p.A2300V | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV70226703; called by muse, mutect2
- DNAH2 | c.10753G>A p.E3585K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as COSV66716716; called by muse, mutect2, varscan2
- DNAH2 | c.11109G>A p.M3703I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs945550079, COSV66716723; called by muse, mutect2, varscan2
- DNAH3 | c.7930C>T p.R2644* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as rs757972267, COSV54505120; called by muse, mutect2, varscan2
- DNAH3 | c.6103G>A p.E2035K | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV54505137; called by muse, varscan2
- DNAH5 | c.10859G>A p.R3620Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs547014532, COSV54205387, COSV54209411; called by muse, mutect2, varscan2
- DNAH5 | c.9418G>A p.E3140K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV54205397; called by muse, mutect2, varscan2
- DNAH8 | c.4870G>A p.D1624N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV59426912; called by muse, mutect2, varscan2
- DNAH8 | c.11195G>A p.R3732K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59426940; called by muse, mutect2, varscan2
- DNAH9 | c.10054G>A p.V3352I | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.699); catalogued as COSV52335494; called by muse, mutect2, varscan2
- DNAJC6 | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54770115; called by muse, mutect2, varscan2
- DNMT3A | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs754037033, COSV53039982, COSV53085140; called by muse, mutect2, varscan2
- DOCK9 | c.2977C>T p.H993Y (on ENST00000376460 / NM_001366676.2; = p.H994Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV59620841; called by muse, mutect2, varscan2
- DPH7 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 62/382 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV53021391; called by muse, mutect2, varscan2
- DPYD | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs200687447, CM145312, COSV64591456; called by muse, mutect2, varscan2
- DPYS | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV60906546; called by muse, mutect2, varscan2
- DRD5 | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58576828; called by muse, varscan2
- DSG1 | c.1405+1G>A p.X469_splice | Splice Site (SNP) | VAF 12/69 reads (17%) | catalogued as COSV57133400; called by muse, mutect2, varscan2
- DSG1 | c.2045G>A p.R682K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.054); catalogued as COSV57133409; called by muse, mutect2, varscan2
- DSG4 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV57388526; called by muse, mutect2, varscan2
- DSG4 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.112); catalogued as rs866537300, COSV57388550; called by muse, mutect2, varscan2
- DSP | c.5828G>A p.R1943K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65791356; called by muse, mutect2, varscan2
- DST | c.18091G>A p.E6031K (on ENST00000361203 / NM_001374722.1; = p.E3728K on NM_015548.5) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.644); catalogued as COSV54999346; called by muse, mutect2, varscan2
- DUXA | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs866701297, COSV73729502; called by muse, mutect2, varscan2
- DYNC2H1 | c.7963G>A p.G2655R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62087010; called by muse, mutect2, varscan2
- DYRK1B | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 27/125 reads (22%) | catalogued as rs1327633157, COSV59912978; called by muse, mutect2, varscan2
- DYSF | c.1379G>A p.R460K | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as CD112839, COSV50270931; called by muse, mutect2, varscan2
- EDNRB | c.400G>A p.E134K (on ENST00000377211 / NM_001201397.1; = p.E44K on NM_000115.5) | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV100526905, COSV57519158; called by muse, mutect2, varscan2
- EEF1A1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV58548958; called by muse, mutect2, varscan2
- ELAVL4 | c.1031C>T p.T344I | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868045736, COSV63914605; called by muse, mutect2, varscan2
- ELOA2 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as rs1459084887, COSV55294019; called by muse, varscan2
- EMB | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as rs553448333, COSV57480670; called by muse, mutect2, varscan2
- EMB | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV57480680; called by muse, mutect2, varscan2
- ENAM | c.2414G>A p.G805D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV68535282; called by muse, mutect2, varscan2
- ENPP6 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.668); catalogued as rs775345484, COSV57065810; called by muse, mutect2, varscan2
- ENTPD7 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV65111957; called by muse, mutect2, varscan2
- EPB41L1 | c.1463C>T p.T488I | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52445468; called by muse, mutect2, varscan2
- EPB41L2 | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1453917219, COSV61353463; called by muse, mutect2, varscan2
- EPB41L4A | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54863070; called by muse, mutect2, varscan2
- EPHA2 | c.2824G>A p.D942N | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.261); catalogued as rs1184554556, COSV100626218, COSV64452174; called by muse, mutect2, varscan2
- EPHA6 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.672); catalogued as COSV67556794; called by muse, mutect2, varscan2
- EPHA6 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV67560246; called by muse, mutect2, varscan2
- EPHA6 | c.2640G>A p.M880I (on ENST00000389672 / NM_001080448.3; = p.M272I on NM_173655.4) | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV67560255; called by muse, mutect2, varscan2
- EPHB6 | c.1910G>A p.S637N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV63890606; called by muse, mutect2
- EPRS1 | c.2458A>C p.I820L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV65097248; called by muse, mutect2, varscan2
- ERAP2 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV65938780; called by muse, mutect2, varscan2
- ERBB3 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV57247402, COSV57260352; called by muse, mutect2, varscan2
- ERC1 | c.1849A>G p.T617A (on ENST00000360905 / NM_178040.4; = p.T589A on NM_178039.4) | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs1022622799, COSV61691821; called by muse, mutect2, varscan2
- ERN2 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56831694; called by muse, mutect2, varscan2
- EXPH5 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.249); catalogued as COSV56199109; called by muse, mutect2
- FABP2 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV56788137; called by muse, mutect2
- FAIM2 | c.451A>G p.T151A | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57737887; called by muse, mutect2, varscan2
- FAM135B | c.3689G>A p.R1230Q | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52706937, COSV99426607; called by muse, mutect2, varscan2
- FAM135B | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs1330919832, COSV52706951; called by muse, mutect2, varscan2
- FAM71E1 | c.521G>A p.G174E (on ENST00000600100 / NM_001308429.2; = p.G158E on NM_138411.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); catalogued as COSV58541655; called by muse, mutect2, varscan2
- FANCD2 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as rs1231761206, COSV55033207; called by muse, mutect2
- FAT4 | c.9200G>A p.G3067E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867017568, COSV58672630; called by muse, mutect2, varscan2
- FBXO24 | c.169A>G p.R57G (on ENST00000241071 / NM_033506.3; = p.R95G on NM_012172.5) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV53823809; called by muse, mutect2
- FDCSP | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.958); catalogued as COSV58764336; called by muse, mutect2, varscan2
- FGB | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV57417559, COSV57419439; called by muse, mutect2, varscan2
- FGF7 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267604241, COSV51065543; called by muse, mutect2, varscan2
- FLG | c.6358G>A p.D2120N | Missense Mutation (SNP) | VAF 53/395 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV64237003; called by muse, mutect2, varscan2
- FLG | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 79/566 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as rs186520508, COSV64237008; called by muse, mutect2, varscan2
- FLRT2 | c.575T>A p.I192N | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58136753; called by muse, mutect2, varscan2
- FMO1 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61444702; called by muse, mutect2, varscan2
- FMO3 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs751472166, COSV63008674; called by muse, mutect2, varscan2
- FNDC1 | c.5609G>A p.G1870E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51931341; called by mutect2, varscan2
- FNDC7 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs761293624, COSV54750945; called by muse, mutect2, varscan2
- FOXD4L3 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100731046; called by mutect2, varscan2
- FOXJ3 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs774386854, COSV100691513, COSV62360072; called by muse, mutect2, varscan2
- FOXK2 | c.1788C>T p.A596= | Splice Region (SNP) | VAF 13/85 reads (15%) | catalogued as rs537784050; called by muse, mutect2, varscan2
- FOXK2 | c.1789G>T p.A597S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.503); catalogued as COSV58883148, COSV58883413; called by muse, varscan2
- FRYL | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV51940337; called by muse, mutect2, varscan2
- FSCB | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 55/224 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV61216624; called by muse, mutect2, varscan2
- FYB2 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.217); catalogued as COSV58583052, COSV58588110; called by muse, mutect2, varscan2
- GABRA3 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1405808499, COSV64795525; called by muse, mutect2, varscan2
- GABRA3 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750973085, COSV64795435; called by muse, mutect2, varscan2
- GALNT15 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV60215443; called by muse, mutect2, varscan2
- GALNT17 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV61148988; called by muse, mutect2
- GALNT18 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs766330240, COSV57158522; called by muse, mutect2, varscan2
- GBP5 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs780439624, COSV58591481; called by muse, mutect2, varscan2
- GCNT1 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV65056821; called by muse, mutect2, varscan2
- GDPD4 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs758515411, COSV60017283, COSV60022331; called by muse, mutect2, varscan2
- GEMIN7 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs147899933; called by muse, mutect2, varscan2
- GIMAP7 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs200815148, COSV57958459; called by muse, mutect2
- GIMAP8 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs754436007, COSV56229877; called by muse, mutect2, varscan2
- GK2 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV62626195; called by muse, mutect2
- GLCE | c.1634T>C p.L545P | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55944382; called by muse, mutect2, varscan2
- GLMP | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55293376; called by muse, mutect2, varscan2
- GNG2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58914412; called by muse, mutect2, varscan2
- GPR158 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.041); catalogued as rs1057413193, COSV66265774; called by muse, mutect2, varscan2
- GPR20 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV66684382; called by muse, mutect2, varscan2
- GPR85 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs1186441151, COSV51782874; called by muse, mutect2
- GPR87 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV53462303; called by muse, mutect2, varscan2
- GPRC6A | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV59951659, COSV59953381; called by muse, mutect2
- GRHL2 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52544892; called by muse, mutect2, varscan2
- GRIA1 | c.2112G>A p.M704I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV53590043; called by muse, mutect2, varscan2
- GRIK2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59709996; called by muse, mutect2, varscan2
- GRIN2A | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.122); catalogued as COSV58021321; called by muse, mutect2, varscan2
- GRK6 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs755000045; called by muse, mutect2, varscan2
- GRK6 | c.264C>T p.A88= | Splice Region (SNP) | VAF 16/142 reads (11%) | catalogued as rs781246618; called by muse, mutect2, varscan2
- GRM3 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV64467564; called by muse, mutect2, varscan2
- GRXCR1 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.992); catalogued as COSV67670217; called by muse, mutect2, varscan2
- GRXCR2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV65060731; called by muse, mutect2, varscan2
- GSDMA | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as COSV52856516; called by muse, mutect2, varscan2
- GUSB | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59220950; called by muse, mutect2
- GZMK | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV50244178; called by muse, mutect2, varscan2
- HABP2 | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1167960175, COSV63635945; called by muse, mutect2, varscan2
- HAL | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.007); catalogued as COSV54116530; called by muse, mutect2, varscan2
- HAVCR2 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as COSV57151847; called by muse, mutect2, varscan2
- HBG1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.851); catalogued as COSV100400730, COSV57963403; called by muse, mutect2, varscan2
- HDC | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as COSV51068370; called by muse, mutect2, varscan2
- HECW2 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs996863763, COSV53650300; called by muse, mutect2
- HELZ | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV62376480; called by muse, mutect2, varscan2
- HEPHL1 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs939355851, COSV59889696; called by muse, mutect2, varscan2
- HFM1 | c.3668+1G>A p.X1223_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as rs565820673, COSV54021566; called by muse, mutect2, varscan2
- HHIPL1 | c.597G>A p.M199I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV58089248; called by muse, mutect2, varscan2
- HID1 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59351060; called by muse, mutect2, varscan2
- HNRNPM | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV57691746; called by muse, mutect2, varscan2
- HOXC13 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54498089, COSV54498710; called by muse, mutect2, varscan2
- HPR | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57181603; called by muse, mutect2, varscan2
- HPS1 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.972); catalogued as COSV57266550; called by muse, mutect2, varscan2
- HRC | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV53255322, COSV99418203; called by muse, mutect2, varscan2
- HRH4 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56927342; called by muse, mutect2, varscan2
- HRNR | c.5663G>A p.G1888E | Missense Mutation (SNP) | VAF 76/1964 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs765912905, COSV64254648; called by muse, mutect2
- HS3ST2 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as rs267604458, COSV54458631; called by muse, mutect2, varscan2
- HSPA13 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53464627; called by muse, mutect2, varscan2
- HSPA8 | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.022); catalogued as COSV57082713; called by muse, mutect2, varscan2
- HSPG2 | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV65969179; called by muse, mutect2
- HTR3B | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.122); catalogued as rs1205832954, COSV52742810; called by muse, mutect2, varscan2
- HYDIN | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55477888; called by muse, mutect2
- ICE2 | c.2642T>C p.V881A | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV55029919; called by muse, mutect2, varscan2
- IFNA16 | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs759718910, COSV66509836; called by muse, mutect2
- IFNA4 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as COSV101427089; called by muse, mutect2, varscan2
- IFNA7 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV53330519; called by muse, mutect2, varscan2
- IFT80 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs754764834, COSV58445611; called by muse, mutect2, varscan2
- IGDCC3 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as rs780318295, COSV100030633, COSV60080517; called by mutect2, varscan2
- IGF1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV61031622, COSV61033552; called by muse, mutect2, varscan2
- IGF2BP2 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs192526034, COSV60483283; called by mutect2, varscan2
- IGF2BP2 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.737); catalogued as COSV60483297; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs534477255; called by muse, mutect2
- IGSF1 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.987); catalogued as rs1270674855, COSV100811768, COSV63836256; called by muse, mutect2, varscan2
- IK | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV70257410, COSV70258172; called by muse, mutect2, varscan2
- IL17A | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV60683928; called by muse, mutect2, varscan2
- IL1RL2 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200105307, COSV51813162; called by muse, mutect2, varscan2
- IL21 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs1324961537, COSV52645503; called by muse, mutect2, varscan2
- IL3 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 80/506 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.722); catalogued as rs371559356, COSV57308448; called by muse, mutect2, varscan2
- IL36B | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 50/131 reads (38%) | catalogued as COSV52084562; called by muse, mutect2, varscan2
- ILDR1 | c.1100G>A p.G367E (on ENST00000344209 / NM_001199799.2; = p.G323E on NM_175924.4) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs866370235, COSV56547877; called by muse, mutect2, varscan2
- IQCN | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV101149199, COSV66572642; called by muse, mutect2, varscan2
- IQUB | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV61237172; called by muse, mutect2, varscan2
- IRF4 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.664); catalogued as COSV66704501, COSV66704941; called by muse, mutect2
- ISX | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58085634; called by muse, mutect2, varscan2
- ITGA4 | c.1836G>A p.M612I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599106, COSV51998079, COSV52000901; called by muse, mutect2
- ITGBL1 | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV66005482; called by muse, mutect2, varscan2
- ITPR1 | c.7507G>A p.E2503K (on ENST00000354582; = p.E2448K on NM_002222.7) | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.108); catalogued as rs756594271, COSV56969990; called by muse, mutect2, varscan2
- JCAD | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as rs751601765, COSV64758110; called by muse, mutect2, varscan2
- JHY | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs1466325661, COSV56218123; called by muse, mutect2, varscan2
- KALRN | c.4217C>T p.S1406F | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53753893; called by muse, mutect2, varscan2
- KAT5 | c.13-6C>T | Splice Region (SNP) | VAF 8/24 reads (33%) | catalogued as rs767147481; called by muse, varscan2
- KAT6B | c.3328C>T p.P1110S | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs761917382, COSV54742576; called by muse, mutect2
- KBTBD12 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59677894; called by muse, mutect2, varscan2
- KCNA5 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV52904045; called by muse, mutect2, varscan2
- KCNB2 | c.2497T>C p.C833R | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.282); catalogued as COSV73049013; called by muse, mutect2, varscan2
- KCNC3 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1179219667, COSV65386727; called by muse, mutect2, varscan2
- KCNH2 | c.1147G>C p.D383H | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51125881, COSV51127091; called by muse, mutect2
- KCNH5 | c.342A>G p.I114M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59752906, COSV59762285; called by muse, mutect2, varscan2
- KCNH6 | c.2972G>A p.S991N | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV59000956; called by muse, mutect2
- KCNH7 | c.2927G>A p.R976K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV59786190; called by muse, mutect2, varscan2
- KCNIP1 | c.247G>A p.D83N (on ENST00000411494 / NM_001034837.3; = p.D72N on NM_014592.4) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV61080693, COSV61086006; called by muse, mutect2, varscan2
- KCNJ4 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV57856210, COSV57856683; called by muse, mutect2, varscan2
- KCNK10 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV56639635; called by muse, mutect2, varscan2
- KCNK16 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV64679544; called by muse, mutect2, varscan2
- KCNQ3 | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.416); catalogued as COSV66464190; called by muse, mutect2, varscan2
- KCTD16 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV72576823; called by muse, mutect2, varscan2
- KCTD20 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); catalogued as rs1462532779, COSV54802266; called by muse, mutect2, varscan2
- KEL | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs866567552, COSV62333443; called by muse, mutect2, varscan2
- KHDRBS2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55429110; called by muse, mutect2, varscan2
- KIAA0232 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV56923416; called by muse, mutect2, varscan2
- KIF4B | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1481965337, COSV70527979; called by muse, mutect2, varscan2
- KIFAP3 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as COSV63031183; called by muse, mutect2, varscan2
- KIR2DL3 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100667805; called by muse, mutect2, varscan2
- KIR2DL3 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.398); catalogued as COSV100668155; called by muse, mutect2, varscan2
- KLK8 | c.231G>A p.P77= | Splice Region (SNP) | VAF 51/237 reads (22%) | catalogued as COSV51590657; called by muse, mutect2, varscan2
- KLRC4 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV58671697; called by muse, mutect2, varscan2
- KMT2A | c.7111C>T p.H2371Y | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as rs1192437631, COSV63282373; called by muse, mutect2, varscan2
- KRBA2 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV58778687; called by muse, mutect2, varscan2
- KRT10 | c.656A>G p.N219S | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.055); catalogued as COSV54088385; called by muse, mutect2, varscan2
- KRT23 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV52927083; called by muse, mutect2, varscan2
- KRT25 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746534406, COSV56443760; called by muse, mutect2, varscan2
- KRT38 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55845286, COSV55845746; called by muse, mutect2, varscan2
- KRT6A | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs1339399303; called by muse, mutect2
- KRT79 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV57938472; called by muse, mutect2, varscan2
- KSR2 | c.2342G>A p.G781E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV56666308; called by muse, mutect2, varscan2
- LGSN | c.929A>T p.D310V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65726310; called by muse, mutect2, varscan2
- LGSN | c.31-1G>A p.X11_splice | Splice Site (SNP) | VAF 5/42 reads (12%) | catalogued as rs1349980354, COSV65726313; called by muse, mutect2, varscan2
- LHX8 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV53954526; called by muse, mutect2, varscan2
- LHX8 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.988); catalogued as COSV53954534; called by muse, mutect2, varscan2
- LILRA1 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV52178109; called by muse, mutect2, varscan2
- LIMCH1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs551919257, COSV58274184; called by muse, mutect2, varscan2
- LMX1A | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54217226; called by mutect2, varscan2
- LNPEP | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51476342, COSV51478576; called by muse, mutect2, varscan2
- LNPEP | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV51476348; called by muse, mutect2, varscan2
- LRP1B | c.3604G>A p.G1202R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV67189237; called by muse, mutect2, varscan2
- LRRC14B | c.967T>C p.F323L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV52043851; called by muse, mutect2, varscan2
- LRRC17 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50864064; called by muse, mutect2, varscan2
- LRRC4B | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65349287; called by muse, mutect2, varscan2
- LRRC4C | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769691883, COSV53418700; called by muse, mutect2, varscan2
- LRRC7 | c.3530C>T p.P1177L (on ENST00000651989 / NM_001370785.2; = p.P1144L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV50413573; called by muse, mutect2, varscan2
- LRRN3 | c.1495A>G p.T499A | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV57817738; called by muse, mutect2, varscan2
- LSM3 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as COSV53203708; called by muse, mutect2, varscan2
- LSR | c.1026G>A p.M342I (on ENST00000361790; = p.M323I on NM_015925.6) | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV55886485; called by muse, mutect2, varscan2
- LVRN | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.179); catalogued as rs140991083, COSV63496114; called by muse, mutect2, varscan2
- LZTR1 | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1305625607, COSV53145381; called by muse, mutect2, varscan2
- MACF1 | c.11005C>T p.R3669C (on ENST00000372915; = p.R1602C on NM_012090.5) | Missense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as rs765567446, COSV57107581; called by mutect2, varscan2
- MAGEC1 | c.2071C>T p.P691S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs1357386902, COSV53568374; called by muse, mutect2, varscan2
- MAGEE2 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.575); catalogued as rs1453669105, COSV64898283; called by muse, mutect2, varscan2
- MAGI1 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs867984285, COSV58346079; called by muse, mutect2
- MAGI2 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62635910; called by muse, mutect2, varscan2
- MAOB | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.66); catalogued as COSV65204342; called by muse, mutect2, varscan2
- MAP7 | c.2013G>A p.E671= | Splice Region (SNP) | VAF 7/57 reads (12%) | catalogued as rs371588242; called by muse, mutect2
- MARS1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.052); catalogued as COSV56252603; called by muse, mutect2, varscan2
- MAST2 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100787799, COSV63616233; called by muse, mutect2, varscan2
- MATR3 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.992); catalogued as COSV63075938; called by muse, mutect2, varscan2
- MCF2 | c.2470G>A p.D824N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV58478299; called by muse, mutect2, varscan2
- MCM10 | c.599C>T p.P200L (on ENST00000484800 / NM_182751.3; = p.P199L on NM_018518.5) | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV66333190; called by muse, mutect2, varscan2
- MCM2 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369079696; called by muse, mutect2, varscan2
- MDGA1 | c.2657G>A p.G886E | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV51792028; called by muse, mutect2, varscan2
- MEAF6 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV56164722; called by muse, mutect2
- MECOM | c.965C>T p.S322F (on ENST00000468789 / NM_001105078.4; = p.S510F on NM_004991.4) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.594); catalogued as COSV52960088; called by muse, mutect2, varscan2
- MED16 | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.828); catalogued as COSV54123512; called by muse, mutect2
- MEGF8 | c.1738T>G p.C580G | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV52075976; called by muse, mutect2, varscan2
- MET | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59257169; called by muse, mutect2, varscan2
- MGAM | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1233061883, COSV72073535; called by muse, mutect2, varscan2
- MGAM | c.5522G>A p.R1841K | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV72073716; called by muse, mutect2
- MGAT4C | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1222715246, COSV59830124, COSV59831777; called by muse, mutect2, varscan2
- MGAT5B | c.2095G>A p.A699T (on ENST00000569840 / NM_001199172.2; = p.A697T on NM_144677.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs748930836, COSV56925595; called by muse, mutect2, varscan2
- MIA2 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.168); catalogued as COSV54482154; called by muse, mutect2
- MIB2 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as COSV61755050; called by muse, mutect2
- MMP26 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1240868007, COSV56171373; called by muse, mutect2, varscan2
- MNDA | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.592); catalogued as rs1328710698, COSV63739987; called by muse, mutect2, varscan2
- MON2 | c.1733C>T p.T578I | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54803470, COSV54809826; called by muse, mutect2, varscan2
- MORC2 | c.586+1G>A p.X196_splice (on ENST00000397641 / NM_001303256.3; = p.X134_splice on NM_014941.3) | Splice Site (SNP) | VAF 17/106 reads (16%) | catalogued as COSV53196438; called by muse, mutect2, varscan2
- MSH3 | c.1840C>T p.H614Y | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.471); catalogued as COSV54145265, COSV54149549; called by muse, mutect2, varscan2
- MTMR7 | c.702C>A p.D234E | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV51663217; called by muse, mutect2, varscan2
- MUC16 | c.40630G>A p.A13544T | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs750892992, COSV66689969; called by muse, mutect2, varscan2
- MUC16 | c.27661G>A p.E9221K | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV67446897; called by muse, mutect2, varscan2
- MUC16 | c.19199G>A p.R6400K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV67446917; called by muse, mutect2, varscan2
- MUC16 | c.10328C>T p.S3443F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV67446934; called by muse, mutect2, varscan2
- MUC16 | c.2696C>T p.P899L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67446940; called by muse, mutect2, varscan2
- MUC17 | c.10985C>T p.T3662I | Missense Mutation (SNP) | VAF 36/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60280897; called by muse, mutect2, varscan2
- MXRA5 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV54224676; called by muse, mutect2, varscan2
- MYCBP2 | c.2587C>T p.P863S (on ENST00000357337; = p.P901S on NM_015057.5) | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.068); catalogued as COSV62010964, COSV62021124; called by muse, mutect2, varscan2
- MYCT1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65890835; called by muse, mutect2, varscan2
- MYH10 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs769801603, COSV52595393; called by muse, mutect2, varscan2
- MYH14 | c.1978G>A p.G660S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.113); catalogued as rs373295946; called by muse, mutect2
- MYH3 | c.2722C>T p.Q908* | Nonsense Mutation (SNP) | VAF 33/117 reads (28%) | catalogued as COSV56861299; called by muse, mutect2, varscan2
- MYH4 | c.2086C>T p.Q696* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV55112733; called by muse, mutect2, varscan2
- MYH4 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55111795; called by muse, mutect2, varscan2
- MYH6 | c.531-1G>A p.X177_splice | Splice Site (SNP) | VAF 26/108 reads (24%) | catalogued as COSV62448057; called by muse, mutect2, varscan2
- MYO10 | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.267); catalogued as rs537148476, COSV57017138; called by muse, mutect2
- MYO5B | c.2245C>T p.R749* | Nonsense Mutation (SNP) | VAF 28/110 reads (25%) | catalogued as rs775529538, CM111504, COSV53211871; called by muse, mutect2, varscan2
- MYO7B | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 26/49 reads (53%) | catalogued as rs1049600482, COSV67344768; called by muse, mutect2, varscan2
- MYOC | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs749154597, COSV50673890, COSV50675387; called by muse, mutect2, varscan2
- MYRF | c.2385_2387del p.E795del (on ENST00000278836 / NM_001127392.3; = p.E786del on NM_013279.4) | In Frame Del (DEL) | VAF 6/65 reads (9%) | catalogued as rs1433683019; called by pindel, varscan2
- NALCN | c.656G>A p.W219* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV51919319, COSV51919540; called by muse, mutect2, varscan2
- NAP1L3 | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV59073834; called by muse, mutect2, varscan2
- NCOR2 | c.5474C>T p.P1825L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV62293596; called by muse, mutect2, varscan2
- NCR1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs587627160, COSV52555483, COSV99401278; called by muse, mutect2, varscan2
- NDRG1 | c.57_58del p.E21Dfs*10 | Frame Shift Del (DEL) | VAF 21/90 reads (23%) | catalogued as COSV60486170; called by mutect2, pindel, varscan2
- NDST4 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52109813; called by muse, mutect2, varscan2
- NDST4 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV52109826; called by muse, mutect2
- NEB | c.3045C>T p.I1015= | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as rs773307085, COSV50857038; called by mutect2, varscan2
- NEK5 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.516); catalogued as COSV62878971; called by muse, mutect2, varscan2
- NEUROD6 | c.771A>T p.E257D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51770122; called by muse, mutect2, varscan2
- NEXMIF | c.1568G>A p.W523* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV50022258; called by muse, mutect2, varscan2
- NFKBIA | c.683A>G p.Q228R | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV53751638; called by muse, mutect2, varscan2
- NLRP12 | c.2507G>A p.G836E | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as COSV100144968, COSV60743784; called by muse, mutect2
- NOS1 | c.2977C>T p.H993Y | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57607313; called by muse, mutect2, varscan2
- NOS2 | c.3355-1G>T p.X1119_splice | Splice Site (SNP) | VAF 14/87 reads (16%) | catalogued as COSV58227676; called by muse, mutect2, varscan2
- NOTCH4 | c.3781G>A p.D1261N | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV66678898; called by muse, mutect2, varscan2
- NOTCH4 | c.3587G>A p.G1196E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV66678640; called by muse, varscan2
- NOTCH4 | c.3548G>A p.G1183E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV66678909, COSV66684035; called by muse, varscan2
- NPAP1 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.801); catalogued as rs868115699, COSV61504054; called by muse, mutect2, varscan2
- NPAP1 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.246); catalogued as COSV61504711; called by muse, mutect2, varscan2
- NPAS4 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.014); catalogued as COSV60648951; called by muse, mutect2, varscan2
- NPAT | c.4154C>T p.S1385F | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1342655741, COSV53716137; called by muse, mutect2
- NR1H4 | c.215C>T p.S72F (on ENST00000551379 / NM_001206993.2; = p.S62F on NM_005123.4) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs868079755, COSV51849579; called by muse, mutect2, varscan2
- NTRK3 | c.2428G>A p.E810K (on ENST00000360948 / NM_001012338.2; = p.E796K on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs550257984, COSV62296439, COSV62299492; called by muse, mutect2, varscan2
- NTSR2 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 50/320 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV60990484; called by muse, mutect2, varscan2
- NUTM2A | c.657del p.Q220Rfs*5 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | catalogued as COSV67742089; called by mutect2, pindel
- NWD1 | c.3848C>T p.P1283L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs267605336, COSV60337989; called by muse, mutect2, varscan2
- NYAP2 | c.1116G>A p.M372I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55997400; called by muse, mutect2, varscan2
- OBP2B | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 27/340 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV64402247; called by muse, mutect2
- OBSCN | c.15745G>A p.G5249R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52743490; called by muse, mutect2
- OR10A4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV65841688, COSV65842072; called by muse, mutect2, varscan2
- OR10C1 | c.385G>A p.E129K (on ENST00000622521; = p.E127K on NM_013941.3) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV65822282; called by muse, mutect2, varscan2
- OR10T2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs371572112; called by mutect2, varscan2
- OR10X1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1184922903, COSV63766973; called by muse, mutect2, varscan2
- OR14I1 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61199000, COSV61199650; called by muse, mutect2, varscan2
- OR1A1 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772402283, COSV58403180; called by muse, mutect2, varscan2
- OR1L4 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52339760; called by muse, mutect2, varscan2
- OR1S1 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58706052; called by muse, mutect2, varscan2
- OR1S2 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV56918419; called by muse, mutect2, varscan2
- OR2B11 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59509320, COSV59510511; called by muse, varscan2
- OR2B3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV65850740; called by muse, mutect2, varscan2
- OR2F2 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV68832562; called by muse, mutect2, varscan2
- OR2G3 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60680733; called by muse, mutect2
- OR2J3 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1308459445, COSV101013667, COSV65848677, COSV99058513; called by muse, mutect2, varscan2
- OR2L13 | c.591G>A p.M197I | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.025); catalogued as rs1431044728, COSV63548510; called by muse, mutect2, varscan2
- OR2M4 | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60707297; called by muse, mutect2, varscan2
- OR2T27 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV61280972; called by muse, mutect2, varscan2
- OR4E2 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); catalogued as COSV57731418; called by muse, mutect2, varscan2
- OR4K14 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1484048244, COSV59292165; called by muse, mutect2, varscan2
- OR4N2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs866280852, COSV60050102; called by muse, mutect2, varscan2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by muse, mutect2, varscan2
- OR51B4 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV66516827; called by muse, mutect2
- OR51B5 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs1356057578, COSV100332369, COSV56175051; called by muse, mutect2, varscan2
- OR51F2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs767787431, COSV59063793; called by muse, mutect2, varscan2
- OR52A5 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV100263283, COSV56614300; called by muse, mutect2, varscan2
- OR52H1 | c.337G>A p.D113N (on ENST00000322653; = p.D119N on NM_001005289.1) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59504930; called by muse, mutect2, varscan2
- OR52N4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs776548473, COSV57890322; called by muse, mutect2, varscan2
- OR56A4 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV58109312; called by muse, mutect2, varscan2
- OR5AC2 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV62279154; called by muse, mutect2, varscan2
- OR5AP2 | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV57256987; called by muse, mutect2, varscan2
- OR5H15 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs377308175, COSV62947393; called by muse, mutect2, varscan2
- OR5H15 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1262654797, COSV62947399, COSV62947727; called by muse, mutect2, varscan2
- OR5W2 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV60614690, COSV60616732, COSV60618306; called by muse, mutect2, varscan2
- OR6K6 | c.469C>T p.P157S (on ENST00000368144; = p.P133S on NM_001005184.1) | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63743643; called by muse, mutect2, varscan2
- OR6T1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770876608, COSV58305477; called by muse, mutect2, varscan2
- OR7C2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV50180241; called by muse, mutect2, varscan2
- OR7G1 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as rs1470753713, COSV53317031; called by muse, mutect2, varscan2
- OR8B8 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs1000946071, COSV60143802; called by muse, mutect2, varscan2
- OR8H2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 58/502 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs868862487, COSV57943241; called by muse, mutect2, varscan2
- OR9A2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs997253838, COSV63306309; called by muse, varscan2
- OR9A2 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63306314; called by muse, mutect2, varscan2
- OR9G1 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56449891; called by muse, mutect2
- OR9G4 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57247785; called by muse, mutect2, varscan2
- OR9K2 | c.928C>T p.P310S (on ENST00000305377; = p.P288S on NM_001005243.1) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs763519211, COSV59531408; called by muse, mutect2, varscan2
- OSBPL6 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51911458; called by muse, mutect2, varscan2
- OTOGL | c.4870G>A p.D1624N (on ENST00000547103; = p.D1615N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.02); catalogued as COSV54013456; called by muse, mutect2
- OXCT1 | c.415-1G>A p.X139_splice | Splice Site (SNP) | VAF 3/50 reads (6%) | catalogued as COSV52167550, COSV52178334; called by muse, mutect2
- P2RY10 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV50680406; called by muse, mutect2, varscan2
- P2RY13 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56369397; called by muse, mutect2, varscan2
- PALLD | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV54973616; called by muse, mutect2, varscan2
- PAPPA | c.1789G>A p.G597R | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60277860; called by muse, mutect2, varscan2
- PAPPA | c.2862-1G>A p.X954_splice | Splice Site (SNP) | VAF 28/142 reads (20%) | catalogued as COSV60276696, COSV60277863; called by muse, mutect2, varscan2
- PAPPA | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV60277872; called by muse, mutect2, varscan2
- PAPPA2 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV62773428; called by muse, mutect2, varscan2
- PAPPA2 | c.4990G>A p.E1664K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV62791247, COSV62794544; called by muse, mutect2, varscan2
- PCDH17 | c.3097C>T p.P1033S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.038); catalogued as rs1243325322, COSV64971937; called by muse, mutect2, varscan2
- PCDHA10 | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV56479706; called by muse, mutect2, varscan2
- PCDHA6 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV65349656; called by muse, mutect2, varscan2
- PCDHB15 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as COSV50859413; called by muse, mutect2, varscan2
- PCDHB5 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as rs267600419, COSV50647432; called by muse, mutect2, varscan2
- PCDHGA1 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.16); catalogued as rs563853936, COSV65295089, COSV65298925; called by muse, mutect2, varscan2
- PCDHGA1 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 68/308 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs746166561, COSV65294883, COSV65295920; called by muse, mutect2, varscan2
- PCDHGB7 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs1360235541, COSV53903679; called by muse, mutect2, varscan2
- PCLO | c.14039G>A p.S4680N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV100436543, COSV61617371; called by mutect2, varscan2
- PCLO | c.4070C>T p.P1357L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61617392; called by muse, mutect2, varscan2
- PCLO | c.3728C>T p.P1243L | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs777818111, COSV61617400; called by muse, mutect2, varscan2
- PCSK5 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65084007; called by muse, mutect2, varscan2
- PCSK5 | c.1287G>A p.W429* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV65084020; called by muse, mutect2, varscan2
- PDE1B | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54489719; called by muse, mutect2, varscan2
- PDE1C | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as rs1160523652, COSV58504063; called by muse, mutect2, varscan2
- PDE7B | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57493058; called by muse, mutect2
- PDYN | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV54100887, COSV99452811, COSV99453431; called by muse, mutect2, varscan2
- PEG3 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs151090043; called by mutect2, varscan2
- PENK | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs376111422; called by muse, mutect2, varscan2
- PGBD1 | c.2338G>A p.A780T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.05); catalogued as COSV52551442; called by muse, mutect2, varscan2
- PHB | c.134T>G p.V45G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV55930697; called by muse, mutect2, varscan2
- PID1 | c.725C>T p.S242F (on ENST00000354069 / NM_001330156.1; = p.S240F on NM_017933.5) | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV62472576; called by muse, mutect2, varscan2
- PIK3C2G | c.651G>A p.W217* | Nonsense Mutation (SNP) | VAF 30/163 reads (18%) | catalogued as COSV56797815; called by muse, varscan2
- PIK3C2G | c.3412G>A p.E1138K (on ENST00000676171; = p.E1097K on NM_004570.5) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56797033; called by muse, mutect2
- PIP4K2C | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769976546, COSV61605714; called by muse, mutect2, varscan2
- PKP1 | c.2078G>A p.R693Q | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs139909774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAAT5 | c.748-1G>A p.X250_splice | Splice Site (SNP) | VAF 12/84 reads (14%) | catalogued as COSV57138546; called by muse, mutect2, varscan2
- PLAG1 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.86); catalogued as COSV57609429; called by muse, mutect2, varscan2
- PLCG1 | c.2945C>T p.S982F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54815548; called by muse, mutect2, varscan2
- PLEKHA7 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV100850254, COSV63043863; called by muse, mutect2
- PLEKHA7 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.091); catalogued as rs1433195596, COSV63043870; called by muse, mutect2, varscan2
- PLEKHG3 | c.2537C>T p.P846L (on ENST00000394691; = p.P902L on NM_001308147.2) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV55977833; called by muse, mutect2, varscan2
- PLEKHJ1 | c.360C>A p.N120K | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.136); catalogued as COSV55553619; called by muse, mutect2, varscan2
- PLS1 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61832795; called by muse, mutect2, varscan2
- PLXDC2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV65900278; called by muse, mutect2, varscan2
- PLXNA4 | c.1803G>A p.M601I | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV58127276; called by muse, mutect2
- PLXNA4 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58106852; called by muse, mutect2, varscan2
- PLXNB2 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV63780206; called by muse, mutect2, varscan2
- POSTN | c.1748A>G p.N583S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV65711954; called by muse, mutect2
- PPL | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs371125122; called by mutect2, varscan2
- PPM1E | c.1951G>A p.G651R | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV57571134; called by muse, mutect2, varscan2
- PPP1R16B | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.621); catalogued as COSV55374436; called by muse, mutect2, varscan2
- PPP1R26 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV63354763; called by muse, mutect2, varscan2
- PPP6C | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65207040; called by muse, mutect2, varscan2
- PRAMEF1 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141554509, COSV60019708; called by muse, mutect2, varscan2
- PRAMEF20 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763463965; called by muse, mutect2, varscan2
- PRB4 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 112/698 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.104); catalogued as COSV54395419; called by muse, varscan2
- PRDM16 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs764674939, COSV54579618; called by muse, mutect2, varscan2
- PRDM16 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV54579632; called by muse, mutect2
- PROS1 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.133); catalogued as COSV67774358; called by muse, mutect2, varscan2
- PRPF18 | c.866A>G p.H289R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60724674; called by muse, mutect2, varscan2
- PRTG | c.3093+1G>A p.X1031_splice | Splice Site (SNP) | VAF 24/136 reads (18%) | catalogued as COSV66836851; called by muse, mutect2, varscan2
- PRUNE2 | c.7763G>A p.G2588E | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs779719853, COSV65038097; called by muse, mutect2, varscan2
- PSEN2 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.95); PolyPhen benign (0.173); catalogued as rs1444327784, COSV60915009; called by muse, mutect2, varscan2
- PSG3 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV59502565; called by muse, mutect2, varscan2
- PTCHD3 | c.1677G>A p.W559* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV71256316; called by muse, mutect2, varscan2
- PTCHD3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as COSV71256317; called by muse, mutect2, varscan2
- PTGDR | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 59/290 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV60093146; called by muse, mutect2, varscan2
- PTPN21 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV60845928; called by muse, mutect2, varscan2
- PTPRC | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV61406860; called by muse, mutect2, varscan2
- PTPRD | c.4333G>A p.E1445K | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866731155, COSV61929861; called by muse, mutect2, varscan2
- PTPRD | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs959497940, COSV61929872; called by muse, mutect2, varscan2
- PTPRN2 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV67023671; called by muse, mutect2, varscan2
- PTPRT | c.2888C>T p.P963L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752831315, COSV61962196; called by muse, mutect2, varscan2
- PTPRT | c.2490C>T p.F830= | Splice Region (SNP) | VAF 137/808 reads (17%) | catalogued as COSV61962200; called by muse, mutect2, varscan2
- PTPRT | c.1518G>A p.W506* | Nonsense Mutation (SNP) | VAF 40/190 reads (21%) | catalogued as COSV61962207; called by muse, mutect2, varscan2
- PTPRT | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.738); catalogued as rs1328589785, COSV61962212; called by muse, varscan2
- PTPRT | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61962219, COSV62009826; called by muse, varscan2
- PUS7L | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV61261231; called by muse, mutect2, varscan2
- QKI | c.261T>A p.Y87* | Nonsense Mutation (SNP) | VAF 33/163 reads (20%) | catalogued as COSV51689746; called by muse, mutect2, varscan2
- QRICH2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.255); catalogued as rs201256631; called by muse, mutect2, varscan2
- RAPGEF6 | c.2893C>T p.L965F | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57240661; called by muse, mutect2, varscan2
- RBBP8NL | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV53348175; called by muse, mutect2, varscan2
- RBM48 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276532250, COSV50394788; called by muse, mutect2, varscan2
- RBMS3 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV56132850; called by muse, varscan2
- RECQL | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV59084365; called by muse, mutect2, varscan2
- REEP1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.981); catalogued as COSV51255836, COSV51259437; called by muse, mutect2, varscan2
- RELN | c.7610G>A p.G2537E | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765712159, COSV59004881; called by muse, mutect2, varscan2
- RELN | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.955); catalogued as rs910972681, COSV58986974; called by muse, mutect2, varscan2
- REN | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV65817346; called by muse, mutect2, varscan2
- REV3L | c.3358C>T p.P1120S | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62615582; called by muse, mutect2, varscan2
- RGS1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV66504606; called by muse, mutect2, varscan2
- RGS3 | c.2990C>T p.S997F (on ENST00000350696 / NM_001282923.2; = p.S716F on NM_130795.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.862); catalogued as COSV59511816; called by muse, mutect2, varscan2
- RGS4 | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.314); catalogued as COSV100905548, COSV63357538; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RIC1 | c.1627G>C p.G543R | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52605281; called by muse, mutect2, varscan2
- RIMS2 | c.2587C>T p.P863S (on ENST00000666250 / NM_001348490.2; = p.P671S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51655205; called by muse, varscan2
- RNF152 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV57183866; called by muse, mutect2, varscan2
- ROGDI | c.845G>A p.W282* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as rs769206420, COSV59023046; called by muse, mutect2, varscan2
- ROR2 | c.947G>A p.C316Y | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65216719; called by muse, varscan2
- RP1 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV55110720; called by muse, mutect2, varscan2
- RP1 | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs866227440, COSV55110739; called by muse, mutect2, varscan2
- RP1 | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV55113016; called by muse, mutect2, varscan2
- RP1 | c.3698C>T p.S1233F | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs867536648, COSV55110747; called by muse, mutect2, varscan2
- RPH3A | c.626G>A p.R209K (on ENST00000389385 / NM_001143854.2; = p.R205K on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV66990026; called by muse, mutect2, varscan2
- RPL38 | c.186dup p.G63Rfs*14 | Frame Shift Ins (INS) | VAF 15/140 reads (11%) | catalogued as rs758386023; called by mutect2, pindel, varscan2
- RPRD2 | c.2125C>T p.Q709* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100955288, COSV64818757; called by muse, mutect2, varscan2
- RPS4Y2 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as COSV56488057; called by muse, mutect2, varscan2
- RSPH10B | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 26/330 reads (8%) | catalogued as rs780371092, COSV58073304, COSV58074236; called by muse, mutect2
- RYR1 | c.2321G>A p.G774E | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62089802; called by muse, mutect2, varscan2
- RYR1 | c.2702G>A p.R901K | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.401); catalogued as COSV62089809; called by muse, mutect2, varscan2
- RYR1 | c.8605C>T p.R2869W | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.33); catalogued as rs956373707, COSV62107828; called by muse, mutect2, varscan2
- RYR2 | c.8905C>T p.P2969S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1383828708, COSV63664182; called by muse, mutect2
- RYR3 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200346395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S1PR1 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59512616; called by muse, mutect2, varscan2
- SAMD9L | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV59079604; called by muse, mutect2, varscan2
- SASS6 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1448610619, COSV54926548; called by muse, mutect2, varscan2
- SBF2 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV56292042; called by muse, mutect2
- SCN10A | c.5177A>T p.N1726I | Missense Mutation (SNP) | VAF 37/128 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV71860353; called by muse, mutect2, varscan2
- SCN11A | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV56566193, COSV56581194; called by muse, mutect2, varscan2
- SCN2A | c.4781G>A p.W1594* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as rs1553463129, COSV51833204; called by muse, mutect2, varscan2
- SCN9A | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445870886, COSV57601030; called by muse, mutect2, varscan2
- SDR16C5 | c.890A>C p.H297P | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV58128581; called by muse, mutect2, varscan2
- SEMA3E | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as rs958373053, COSV57080534; called by muse, mutect2
- SEMA5B | c.1048G>A p.G350S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774780742, COSV52108812; called by muse, mutect2, varscan2
- SERPINB4 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as rs750116682, COSV61984264; called by muse, mutect2, varscan2
- SERPINB7 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as COSV60532713; called by muse, mutect2, varscan2
- SGCA | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56248459; called by muse, mutect2, varscan2
- SGO2 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as rs777890121, COSV63414037; called by muse, mutect2, varscan2
- SH2B1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.108); catalogued as COSV59460742; called by muse, mutect2, varscan2
- SH2D7 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs867137500, COSV60926025; called by muse, mutect2, varscan2
- SH3GLB1 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.231); catalogued as COSV65279186; called by muse, mutect2, varscan2
- SH3RF2 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 54/333 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV63037295; called by muse, mutect2, varscan2
- SHANK3 | c.3178G>A p.D1060N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.649); catalogued as rs1220988227, COSV53183730; called by muse, mutect2, varscan2
- SHC2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs374025306; called by muse, mutect2, varscan2
- SI | c.765G>A p.W255* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV52267005; called by muse, mutect2, varscan2
- SIGLEC12 | c.1373C>T p.S458F (on ENST00000291707 / NM_053003.4; = p.S340F on NM_033329.2) | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs977432447, COSV52459503; called by muse, mutect2, varscan2
- SIGLEC12 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs868615338, COSV52459250; called by muse, mutect2, varscan2
- SIGLEC6 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV58432071; called by muse, mutect2, varscan2
- SIPA1L1 | c.5104G>A p.E1702K | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.951); catalogued as rs1437035725, COSV62168649; called by muse, mutect2, varscan2
- SLC13A4 | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762375698, COSV62460055; called by muse, mutect2, varscan2
- SLC13A5 | c.1403C>T p.T468I | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV53421729; called by muse, mutect2, varscan2
- SLC15A2 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55196129; called by muse, mutect2, varscan2
- SLC15A2 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs267599571, COSV55196140; called by muse, mutect2, varscan2
- SLC16A9 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68098318; called by muse, mutect2, varscan2
- SLC16A9 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV68098322; called by muse, mutect2, varscan2
- SLC1A5 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.291); catalogued as COSV69466494; called by muse, mutect2, varscan2
- SLC1A6 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV55668178; called by muse, mutect2, varscan2
- SLC22A25 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as rs1208140740, COSV60594617; called by muse, mutect2, varscan2
- SLC26A5 | c.1390A>G p.T464A | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV59698346; called by muse, varscan2
- SLC36A1 | c.1412C>T p.S471F | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV54652223; called by muse, mutect2, varscan2
- SLC3A2 | c.913A>C p.I305L | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV58602868; called by muse, mutect2, varscan2
- SLC44A4 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs1270129377, COSV57665869; called by muse, mutect2
- SLC5A7 | c.457A>T p.I153F | Missense Mutation (SNP) | VAF 142/378 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV50889032; called by muse, mutect2, varscan2
- SLC5A8 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs866410623, COSV73310380; called by muse, mutect2, varscan2
- SLC66A1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV64320564; called by muse, mutect2, varscan2
- SLC6A3 | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 31/109 reads (28%) | catalogued as COSV54361785; called by muse, mutect2, varscan2
- SLC9C2 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV62943997; called by muse, mutect2, varscan2
- SLIT2 | c.2363G>A p.R788K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56596756; called by muse, mutect2
- SLIT3 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.262); catalogued as rs534754485, COSV60592084; called by muse, mutect2, varscan2
- SLITRK6 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV68389409; called by muse, mutect2, varscan2
- SMARCA4 | c.4511C>T p.P1504L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60787170; called by muse, mutect2, varscan2
- SMC6 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61171584; called by muse, mutect2, varscan2
- SMPD3 | c.1807G>A p.G603S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773584897, COSV54710533; called by muse, mutect2, varscan2
- SNAP91 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV52115886, COSV52115955; called by muse, mutect2, varscan2
- SPACA1 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52759070; called by muse, mutect2, varscan2
- SPAM1 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.78); catalogued as COSV56141264; called by muse, mutect2, varscan2
- SPANXN2 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 109/344 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100979825, COSV65127756; called by muse, varscan2
- SPATA18 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV54641891; called by muse, mutect2
- SPATA20 | c.230C>T p.A77V (on ENST00000356488 / NM_001258372.1; = p.A93V on NM_022827.4) | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50065857; called by muse, mutect2
- SPATA31D1 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV61193029; called by muse, mutect2, varscan2
- SPHKAP | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV60869360; called by muse, mutect2, varscan2
- SPINK5 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV56248617; called by muse, mutect2, varscan2
- SPRING1 | c.382T>A p.Y128N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54338264; called by muse, varscan2
- SPTA1 | c.5614G>A p.E1872K | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV63749317; called by muse, mutect2, varscan2
- SRGAP3 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.757); catalogued as rs956102117, COSV64530715; called by muse, mutect2, varscan2
- SSH3 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57386933; called by muse, mutect2, varscan2
- SSPOP | n.1909G>A | Splice Region (SNP) | VAF 5/19 reads (26%) | catalogued as rs538766942, COSV50486496; called by muse, mutect2
- ST8SIA4 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | PolyPhen probably damaging (0.956); catalogued as COSV51506467; called by muse, mutect2, varscan2
- STAC | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs1359357165; called by muse, mutect2, varscan2
- STARD13 | c.3048G>A p.R1016= (on ENST00000336934 / NM_001243476.3; = p.R898= on NM_052851.3) | Splice Region (SNP) | VAF 12/93 reads (13%) | catalogued as COSV55227509; called by muse, mutect2, varscan2
- STEAP4 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV57328130, COSV57331236; called by muse, mutect2, varscan2
- STK31 | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV63454200; called by muse, mutect2
- STPG4 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54277976; called by muse, mutect2
- STXBP5L | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56501250; called by muse, mutect2, varscan2
- SULT1B1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as rs761640326, COSV60206584; called by muse, mutect2, varscan2
- SV2B | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as COSV57698594; called by muse, mutect2, varscan2
- SVOP | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV54464178; called by muse, mutect2, varscan2
- SYNPO2 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61107011; called by muse, mutect2, varscan2
- SYT10 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57337864; called by muse, mutect2, varscan2
- SYT16 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.638); catalogued as COSV70855113; called by muse, mutect2, varscan2
- TACC2 | c.5633C>T p.T1878I (on ENST00000334433; = p.T69I on NM_206861.3) | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs759153407, COSV57747029; called by muse, mutect2, varscan2
- TAOK2 | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 36/276 reads (13%) | catalogued as COSV54233410; called by muse, mutect2, varscan2
- TAS2R38 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as COSV71884999; called by muse, mutect2
- TAS2R39 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as rs570396081, COSV71470805; called by muse, varscan2
675 further variants in this file (167 protein-altering or splice-affecting, 483 silent, 25 other) are not listed here.
